TCGA case TCGA-D3-A2JF — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c58638ed-a38c-4494-a41e-6ee5283a7a59

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 74 years; Vital status: Alive.

Diagnoses (8)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C49.1; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Classification of tumor: metastasis; Age at diagnosis: 76.1 years (27,799 days); Days to diagnosis: 544 days (1.5 years); Prior treatment: No; Days to last follow up: 1,888 days (5.2 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 74.6 years (27,255 days); Year of diagnosis: 2008; AJCC staging edition: 7th; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
3. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Skin of other and unspecified parts of face; Laterality: Right; Classification of tumor: Prior primary.
4. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: III; Sites of involvement: Skin, Extremities / Skin, Trunk; Ulceration indicator: No.
   Pathology details: Breslow thickness category: <=1 mm.
   Recorded as not given: Radiation Therapy, NOS.
5. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lower limb, NOS; Laterality: Right; Classification of tumor: Prior primary.
6. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin of trunk; Classification of tumor: Subsequent Primary; Age at diagnosis: 74.7 years (27,280 days); Days to diagnosis: 25 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 45 days.
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Radiation Therapy, NOS, for initial diagnosis.
7. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Connective, subcutaneous and other soft tissues of upper limb and shoulder. Age at diagnosis: 76.1 years (27,799 days); Days to diagnosis: 544 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 588 days (1.6 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease.
8. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: Subsequent Primary; Age at diagnosis: 78.3 years (28,590 days); Days to diagnosis: 1,335 days (3.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 1,348 days (3.7 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis.

Follow-up (3 entries)
- Day 544 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Days to progression: 544 days (1.5 years).
- Days to follow up: 1,483 days (4.1 years); Disease response: Tumor Free.
- Days to follow up: 1,888 days (5.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 0.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80 kg; Height: 170 cm; BMI: 27.7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D3-A2JF-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-D3-A2JF-06A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-D3-A2JF-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D3-A2JF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Breslow thickness at diagnosis: 0.28; Primary melanoma tumor ulceration: No; Primary melanoma mitotic rate: 0; Radiation therapy to primary: No; Primary location: Distant Metastasis; Metastatic tumor site: Left arm, soft tissue; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site 1: Submitted tumor site: Extremities; Melanoma primary count: 1.
- Sites of primary melanomas, Site 2: Submitted tumor site: Trunk; Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Subsequent known primaries: No.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Nose, Skin; Other malignancy histological type: Squamous Cell Carcinoma, Not Otherwise Specified.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Leg; Other malignancy histological type: Squamous Cell Carcinoma, Not Otherwise Specified.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: systemic treatment.
- Prior malignancy: Patient had a prior squamous cell carincoma of the skin on the nose and leg. No radiation or systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,888 days; disease-specific survival: no event (censored), 1,888 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 25 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D3-A2JF-06A-11D-A194-01): tumor purity 0.58, ploidy 3.33, whole-genome doublings 1.
